Somatic mutation profile of tumor specimen HCM-BROD-0041-C64-01A (aliquot HCM-BROD-0041-C64-01A-11D-A79L-36) from HCMI case HCM-BROD-0041-C64, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 7.3 years (2,655 days).
Specimen HCM-BROD-0041-C64-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54054fe8-d4a0-4dac-940a-ef451b22503a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0041-C64-10A (Blood Derived Normal), aliquot HCM-BROD-0041-C64-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0156ded1-a016-4d6c-a389-010d18aba7b7

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 14, Silent 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYCN | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 500/882 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519919, COSV55257406, COSV55259752; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1998G>T p.K666N | Missense Mutation (SNP) | VAF 180/324 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs377023736, COSV59205777, COSV59205799; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 322/335 reads (96%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CGNL1 | c.3043C>T p.R1015C | Missense Mutation (SNP) | VAF 16/177 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.917); catalogued as rs138103109, COSV55562951; called by muse, mutect2
- FAM236D | c.232G>A p.G78R (on ENST00000419795 / NM_001348203.1; = p.G74R on NM_001348202.1) | Missense Mutation (SNP) | VAF 139/265 reads (52%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as rs1356637466; called by muse, mutect2, varscan2
- NDST2 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 156/471 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs371391594; called by muse, mutect2, varscan2
- OTOGL | c.575G>A p.R192Q (on ENST00000547103; = p.R183Q on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/362 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs540892936, COSV72006457, COSV72007011; called by muse, mutect2
- SETD7 | c.228C>G p.Y76* | Nonsense Mutation (SNP) | VAF 34/241 reads (14%) | catalogued as COSV99918418; called by muse, mutect2, varscan2
- ZNF366 | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 50/834 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as rs753571275; called by muse, mutect2
- CCDC141 | c.4491C>G p.H1497Q | Missense Mutation (SNP) | VAF 118/352 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CHI3L1 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 34/266 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LUZP1 | c.2260G>A p.A754T | Missense Mutation (SNP) | VAF 24/326 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2
- RAD51AP1 | c.674G>T p.R225I (on ENST00000228843 / NM_001130862.2; = p.R208I on NM_006479.5) | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- TCTE1 | c.17C>T p.T6M | Missense Mutation (SNP) | VAF 45/338 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZNF679 | c.1219C>A p.P407T | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- CACNA1E | c.5322G>A p.P1774= | Silent (SNP) | VAF 42/583 reads (7%) | catalogued as rs753481808, COSV62382273; called by muse, mutect2
- DNAH17 | c.1053C>T p.T351= | Silent (SNP) | VAF 52/277 reads (19%) | catalogued as rs772633687; called by muse, mutect2, varscan2
- LTB | c.531G>T p.L177= | Silent (SNP) | VAF 32/1152 reads (3%) | catalogued as rs1426018729; called by muse, mutect2
- MTOR | c.3777C>T p.H1259= | Silent (SNP) | VAF 64/396 reads (16%) | catalogued as rs755448166; called by muse, mutect2, varscan2
- ZFHX4 | c.8415G>A p.S2805= | Silent (SNP) | VAF 77/433 reads (18%) | catalogued as rs368980001; called by muse, mutect2, varscan2
